Somatic mutation profile of tumor specimen MP2PRT-PAUIRM-TMP1-A (aliquot MP2PRT-PAUIRM-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUIRM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,764 days).
Specimen MP2PRT-PAUIRM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c124a03c-0ebe-47ee-9331-510a7d454340.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUIRM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUIRM-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca8efa0a-0811-4f86-98dc-a75bd98ba062

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CADPS | c.265C>A p.P89T | Missense Mutation (SNP) | VAF 106/306 reads (35%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99032524; called by muse, mutect2, varscan2
- CNTNAP3 | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 37/818 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as COSV99904752; called by muse, mutect2
- GTF3C1 | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.226); catalogued as rs769320273, COSV62243009; called by muse, mutect2, varscan2
- XCR1 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 132/381 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as rs780739360, COSV58570473; called by muse, mutect2, varscan2
- DSG4 | c.2842G>A p.G948R | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- OR5H6 | c.311A>T p.K104M (on ENST00000642105; = p.K88M on NM_001005479.2) | Missense Mutation (SNP) | VAF 85/199 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ADAM10 | c.501C>T p.Y167= | Silent (SNP) | VAF 94/249 reads (38%) | catalogued as rs200804344; called by muse, mutect2, varscan2
